Surgical pathology report (de-identified scan), TCGA case TCGA-BS-A0T9, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of Hawaii, specimen TCGA-BS-A0T9-01A (Primary Tumor).

[page 1 of 4]
Surgical Pathology Report

Patient Name:

Med Rec No:

DOB:

Gender:

Physician(s):

cc:

Client:

Location:

Pt. Phone no

Accession #:

Taken:

Received:

Reported:

History/Clinical Dx: Menometrorrhagia, severe anemia, possible endometrial cancer

Postoperative Dx: Pending pathology examination

Specimen(s) Received:

- A: Omentum
- B: Peri-cecal implant
- C: Distal ileal implant
- D: Abdominal implant
- E: Uterus, cervix
- F: Right ovary and tube
- G: Left ovary and tube
- H: Left pelvic lymph node
- I: Left aortic lymph node
- J: Right pelvic lymph node

10A-0-3

adenocarcinoma, endometrioid, NOS 8380/3

Site: Endometrium 054.1

10/27/11

DIAGNOSIS:

- A. Omentum: Metastatic poorly differentiated carcinoma consistent with primary endometrial carcinoma
- B. Peri-cecal implant: Benign cyst
- C. Distal ileal implant: Fibrous tissue with keratin granulomas, negative for malignancy
- D. Abdominal implant: Fibrous tissue with keratin granulomas, negative for malignancy
- E. Uterus, cervix: ENDOMETRIAL ADENOCARCINOMA

Tumor Information:

- Operative procedure: Total abdominal hysterectomy with bilateral salphingo-oophorectomy and pelvic lymph node dissection
- Histologic type: Endometrial adenocarcinoma
- Histologic grade(FIGO): Grade III
- Nuclear grade: Grade III
- Tumor size: 11 x 5 x 3 cm
- Extent of invasion: More than 2/3 of the myometrial thickness
- Lympho/vascular invasion: Present
- Serosa: Uninvolved by tumor, keratin granulomas present

Regulatory Statement:

This laboratory is not responsible for the use of the results of this report in the management of the patient. The use of the results of this report in the management of the patient is the responsibility of the clinician. The use of the results of this report in the management of the patient is the responsibility of the clinician. The use of the results of this report in the management of the patient is the responsibility of the clinician.

[page 2 of 4]
Surgical Pathology Report

Parametrium:	Involved bilaterally
Cervical involvement:	Present
Right adnexa:	Free of tumor
Left adnexa:	Free of tumor
Special studies:	None
Staging information:	T3a, N1, M1, Stage IVB

F. Right ovary and tube:	No evidence of malignancy
G. Left ovary and tube:	No evidence of malignancy
H. Left pelvic lymph node:	1 of 1 pelvic lymph node positive for metastasis (1/1)
I. Left aortic lymph node:	1 of 2 lymph nodes positive for metastases (1/2)
J. Right pelvic lymph node:	1 of 1 lymph node positive for metastases (1/1)

Intraoperative Consultation:

D. Frozen Section Interpretation: Benign fibromembranous tissue with acute inflammation/KT

Gross Description

A. Received in formalin labeled "omentum" consist of a single fragment of pale yellow fibrofatty tissue weighing 108 gm, measuring 22.0 x 7.5 x 0.5 cm. There is a piece of clear suture at one end. Representative sections are submitted in four cassettes.

B. Received in formalin labeled "pericecal implant" consist of a single pale tan, pale yellow tissue fragment weighing <1gm, measuring 0.5 x 0.4 x 0.2 cm. Submitted in toto.

C. Received in formalin labeled "distal ilial implant" consist of multiple tan, white tissue fragment having a combined weight of <1 gm, measuring in aggregate 1.6 x 0.8 x 0.2 cm. Submitted in toto.

D. Received fresh labeled "abdominal implant for frozen section" consist of two fragments of white, pink tissue with a combined weight of <1gm. The largest fragment measures 0.6 x 0.2 x 0.2 cm. The smallest fragment measures 0.2 x 0.1 x 0.1 cm. The two fragments are submitted in toto for frozen section and permanent sections.

E. Received: In formalin, previously opened, uterus with cervix
Labeled: Uterus and cervix
Weight: 275 gm
Size:
Uterus: 11.0 x 9.0 x 7.0 cm
Appearance
Tumor

Location:	Endometrial cavity extending to the lower uterine segment and protruding from the cervix
Configuration:	Polypoid, in areas of papillary excrescences
Size:	11.0 x 5.0 x 3.0 cm
Appearance:	Tan, friable, focal areas of hemorrhage
Depth of invasion:	More than 2/3 into the myometrium
Extent:	The tumor involves the entire endometrial cavity, bilateral cornu and extends to the cervix
Invasion of contiguous structures:	Not identified
Distance from margins:	Right parametrium (inked blue) 0.3 cm, left parametrium (inked green) 0.2 cm

Cervix: The anterior cervix is involved by the tumor and the tumor protrudes from the cervical os
Endometrium: Grossly no uninvolved endometrium is identified
Myometrium: Up to 2.5 cm in thickness with focal areas of adenomyosis
Right tube and ovary: Submitted separately
Left tube and ovary: Submitted separately

[page 3 of 4]
Surgical Pathology Report

Lymph nodes: None
Special studies: None
Other: Tumor implants identified on the serosal surface measuring up to 0.5 cm.

Description of blocks:

- 1-2 - Anterior cervix
- 3 - Posterior cervix
- 4 - Right parametrium
- 5 - Left parametrium
- 6-7 - Tumor at lower uterine segment
- 8-9 - Tumor
- 10 - Serosal implant
- Full thickness endometrium and myometrium

- F. Received in formalin labeled "right ovary and tube" consist of a tube and ovary with a portion missing. The tube and ovary weighs 16 gm, measures overall 7.0 x 4.5 x 1.0 cm. Representative sections are submitted.
- G. Received in formalin labeled "left ovary and tube" consist of a tube and ovary with a portion missing. The tube and ovary weighs 16 gm, measures overall 7.0 x 4.0 x 1.0 cm. Representative sections are submitted.
- H. Received in formalin labeled "left pelvic lymph node" is a firm, tan nodule with attached fatty tissue measuring 2.5 x 2.0 x 1.5 cm and weighing 4 gm. Submitted entirely in two cassettes.
- I. Received in formalin labeled "left aortic lymph node" is a piece of fibrofatty tissue with lymph node measuring 3.6 x 1.5 x 1.0 cm, weighing 2 gm. Grossly two lymph nodes are identified. Submitted entirely in two cassettes, each cassette has a single lymph node.
- * Received in formalin labeled "right pelvic lymph node" is a tan to firm, oval piece of tissue with attached fatty tissue measuring 4.0 x 3.0 x 2.0 cm, weighing 9 gm. Submitted representative in one cassette.

Microscopic Description

A-J. The microscopic findings support the above diagnoses.

[page 4 of 4]
PATIENT INFORMATION FORM

Study ID# _____ MedRec# _____ Path Date: _____ Path# _____

Name: _____ Birthdate: _____

Home Address: _____ Home Phone: _____ Diagnosis Age: _____

Mailing Address: _____ Other Phone: _____ Race: _____

Marital: _____ Occupation: _____ OVS id#: _____

Consent Date: _____ Blood Date: _____ Surgery Date: _____

Hospital: _____ Physician: _____ Pathologist: _____ Death date: _____

Consent? 1 Demog? 1 Tissue? 1 Path Report? 1 Assign? 1

Site: **Uterus** Cancer Type: **Endometrioid adenocarcinoma**

Diagnosis Info: TAH-BSO: Uterus, cervix: Endometrial adenocarcinoma. Histologic type: endometrioid; grade 3; stage T2a, N1, M1. Extent of invasion: More than 2/3 of myometrial thickness. Cervical involvement present; Serosa: uninvolved, keratin granulomas present. Parametrium: involved bilaterally. 3 of 4 lymph nodes positive for metastasis. Omentum: metastatic poorly differentiated carcinoma consistent with primary endometrial carcinoma. Right and left adnexa free of tumor. Bilateral tubes & ovaries: no evidence of malignancy.

PC Notes:

Assign Date: _____

Source: NCI Genomic Data Commons file 8ed2a135-717d-4949-8047-b899da15748a (TCGA-BS-A0T9.C9151621-D012-48F9-B7E1-F540567E791C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).